Surgical pathology report (de-identified scan), TCGA case TCGA-E7-A541, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site Asterand, specimen TCGA-E7-A541-01A (Primary Tumor).

[page 1 of 2]
Gross Description: Piece of radical cystectomy with a whitish, solid, and vegetative tumor developed at the level of the right hemibladder

Microscopic Description: Histological aspect: urothelial carcinoma, G3, poorly differentiated, with alveolar and papillary pattern, unevenly invasive into the chorion and into the deep and superficial musculature, but without surpassing it; with an important inflammatory infiltrate arranged as lymphoid aggregates, which limits the tumoral invasion hotbeds; the urethral lining with preserved architecture to the level of the surgical segment; prostate with small tumoral hotbeds of acinar adenocarcinoma with infiltrative glandular pattern at the level of one of the lobes; seminal vesicles - morphologically undamaged.

2. Group of four lymph nodes without tumoral metastases.
3. Lymph nodes with reactive lymphoid hyperplasia, without tumoral metastases.
4. Two small histotypic lymph nodes.
5. Small segment of ureter with slightly dilated lumen.
6. Small segment of ureter with dilated lumen and non-specific inflammatory infiltrate diffusely distributed into the chorion.

Diagnosis Details: CONCLUSION: 1. Invasive urothelial carcinoma of the bladder, poorly differentiated, G3, pT2b pNo pMx.

2. Acinar adenocarcinoma of the prostate, histological score Gleason 6 (3+3), pT2a pNx pMx.

Comments:

Formatted Path Reports: BLADDER TISSUE CHECKLIST

Specimen type: Radical cystectomy

Tumor site: Bladder

Tumor size: Not specified

Tumor features: Papillary

Histologic type: Papillary transitional cell carcinoma

Histologic grade: Poorly differentiated

Tumor extent: Muscularis propria

ICD-0-3

carcinoma, papillary transitional cell 8130/3
Site: bladder, NOS C67.9

hw
11/20/12

[page 2 of 2]
Lymph nodes: 0/7 positive for metastasis (Left and right ilio-obturator 0/7)

Lymphatic invasion: Present

Venous invasion: Not specified

Margins: Not specified

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: The path report doesn't specify the tumor size. For bladder cancer the T grade is given by the level of tumor extension in through the wall not the tumor size. So, tumor size is not relevant for the pathologist and he/she doesn't always record its dimensions.

Comments: Wall, anterior

Reviewed Initials	11/19/12	

Source: NCI Genomic Data Commons file 22ba01a0-2326-433e-954a-3e251b7cc344 (TCGA-E7-A541.2363E39A-F372-406C-B41B-E2260D50611D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).